CCDI case PBCKTP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/26cdb669-1772-4fc5-9141-945856e991c0

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 11.3 years (4,135 days).

Biospecimens (3 samples)
- Samples 0DU7ZY, 0DU81G (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU80E: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
